Gene-level copy-number profile of tumor specimen TCGA-HQ-A2OE-01A from TCGA case TCGA-HQ-A2OE, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS.
Specimen TCGA-HQ-A2OE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.e8a9c271-0fca-4496-a039-5533b030c361.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HQ-A2OE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aadce7a5-0845-4266-aa66-4003b99833db

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,172; copy number 2: 14,701; copy number 3: 13,751; copy number 4: 11,226; copy number 5: 13,445; copy number 6: 4,417; copy number 7: 849; copy number 8: 210; copy number 9: 4; copy number 10: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HQ-A2OE-01A-11D-A201-01): tumor purity 0.8, ploidy 3.57, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18,090 genes in 40 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:21,977,022–52,894,998, 960 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:54,514,417–62,710,694, 119 genes, copy number 5 (broad region; genes not listed).
- chr1:66,999,350–74,544,393, 92 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:74,341,579–74,378,802, 1 gene, copy number 5: AC093158.1.
- chr1:85,265,776–88,685,204, 43 genes, copy number 5 (within-gene range 3–5): BCL10, AL078459.1, DDAH1, Y_RNA, AL360219.1, AC092807.3, AC092807.2, CCN1, SNORD81, AC092807.1, ZNHIT6, COL24A1, RNA5SP51, AC104455.1, LINC02795, ODF2L, MIR7856, AC119749.1, CLCA2, CLCA1, CLCA4, CDCA4P2, CLCA4-AS1, CLCA3P, CLCA4-AS1, SH3GLB1, AL049597.1, AL355981.1, SELENOF, HS2ST1, AL121989.1, AC093155.3, AC093155.2, AC093155.1, LINC01140, LINC02801, LMO4, LINC01364, RNA5SP52, PKN2-AS1, AL445437.1, AL049861.1, AL445438.1.
- chr1:110,947,190–248,919,946, 2,864 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:38,814–49,888,986, 837 genes, copy number 5–7 (broad region; genes not listed).
- chr2:50,324,643–50,345,598, 1 gene, copy number 6: AC068725.1.
- chr2:52,722,671–94,604,573, 786 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr2:164,840,661–165,208,261, 1 gene, copy number 5 (within-gene range 4–5): AC019197.1.
- chr2:165,087,526–165,436,614, 4 genes, copy number 5: SCN3A, SCN2A, MAPRE1P3, AC011303.1.
- chr2:168,451,324–169,362,534, 13 genes, copy number 6: RN7SL813P, CERS6, MIR4774, RNU6-766P, CERS6-AS1, NOSTRIN, SPC25, G6PC2, ABCB11, DHRS9, AC007556.1, UBE2V1P6, LRP2.
- chr2:191,834,310–192,776,899, 9 genes, copy number 7–8: CAVIN2, CAVIN2-AS1, DNAJB1P1, TMEFF2, AC062039.1, AC013401.1, PCGEM1, RPS17P8, AC013401.2.
- chr3:11,745–44,338,552, 653 genes, copy number 5 (broad region; genes not listed).
- chr3:75,664,330–90,261,708, 95 genes, copy number 6–8 (broad region; genes not listed).
- chr4:86,823,468–87,786,371, 27 genes, copy number 5: SLC10A6, AC093827.1, C4orf36, AC093827.2, AC093827.5, AC093827.3, AC093827.4, AFF1, TECRP1, KLHL8, AC092658.1, GAPDHP60, AC108516.1, MIR5705, HSD17B13, AC108516.2, HSD17B11, RN7SL681P, AC112250.1, NUDT9, AC112250.2, SPARCL1, AC093895.1, DSPP, DMP1, Y_RNA, CHCHD2P7.
- chr4:116,714,844–117,085,576, 7 genes, copy number 5: AC093765.5, AC093765.4, AC093765.3, AC093765.2, RNU6-119P, AC093765.1, TRAM1L1.
- chr5:43,006,733–45,895,970, 46 genes, copy number 5: AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224, AC093292.1, RN7SL383P, MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:3,268,962–3,457,050, 1 gene, copy number 6 (within-gene range 4–6): SLC22A23.
- chr6:3,585,101–22,654,455, 298 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:96,481,626–148,420,998, 1,069 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr7:149,239,651–155,003,124, 135 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:88,032,011–145,066,685, 902 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr10:44,712–21,293,011, 346 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr10:30,723,251–55,627,942, 413 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr10:110,497,907–133,761,125, 399 genes, copy number 5 (broad region; genes not listed).
- chr12:66,767–133,214,832, 3,050 genes, copy number 6–8 (broad region; genes not listed).
- chr16:425,649–523,011, 1 gene, copy number 7 (within-gene range 2–7): RAB11FIP3.
- chr16:451,404–2,196,605, 163 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr16:6,748,908–7,126,639, 4 genes, copy number 5–10: RNU7-99P, RNU6-457P, RNU6-328P, AC022206.1.
- chr16:7,614,230–7,726,951, 2 genes, copy number 7: AC005774.2, AC005774.1.
- chr16:8,615,855–11,976,643, 102 genes, copy number 5 (broad region; genes not listed).
- chr16:11,976,851–12,095,307, 4 genes, copy number 5: AC007216.1, RPS23P6, AC007601.1, AC007601.2.
- chr17:22,056,587–83,095,122, 2,150 genes, copy number 5–6 (broad region; genes not listed).
- chr19:50,825,289–53,731,090, 231 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:56,397,966–58,315,183, 112 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:31,257,664–38,442,169, 260 genes, copy number 5–8 (broad region; genes not listed).
- chr20:39,655,325–54,228,052, 334 genes, copy number 5–6 (broad region; genes not listed).
- chr20:55,607,852–64,313,132, 260 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr22:15,290,718–49,052,549, 1,296 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 563. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
